Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A5GR, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A5GR-06A (Metastatic).

[page 1 of 2]
DIAGNOSIS

(A) LEFT INGUINAL FOSSA, LYMPHADENECTOMY:
MELANOMA, METASTATIC TO TWO OF SIX LYMPH NODES (2/6).
Largest tumor deposit size: 65 x 45 mm (gross measurement).
Location: Subcapsular and intraparenchymal
Extracapsular extension: Present.
Skin and subcutis with changes of healing surgical wound.
See comment.

(B) COMMON ILIAC LYMPH NODES, LYMPHADENECTOMY:
Eleven lymph nodes, melanoma is not identified, (0/11).

(C) LEFT OBTURATOR NODE, LYMPHADENECTOMY:
MELANOMA, METASTATIC TO ONE OF NINE LYMPH NODES (1/9).
Largest tumor deposit size: 0.8 x 0.6 mm.
Location: Intraparenchymal
Extracapsular extension: Not identified.
See comment.

(D) LEFT STERNAL ILIAC NODES, LYMPHADENECTOMY:
Seventeen lymph nodes, melanoma is not identified, (0/17).

ICD-O-3
Melanoma, malignant NOS
8720/3
Site: Inguinal lymph Node
C77.4
QW 4/4/13

COMMENT

(A, C) Comparison is made to this patient's prior specimen (see and the tumor cells in the current specimen are morphologically similar, supporting the above diagnoses.

GROSS DESCRIPTION

(A) CONTENTS OF LEFT INGUINAL FOSSA – Soft tissue containing large lymph nodes (13.0 x 12.0 x 5.0 cm), overlying skin which is light tan (6.0 x 2.5 cm), lymph nodes which range from 1.0 cm to the largest measuring (6.5 x 4.5 x 4.0 cm). The largest node is grossly positive with areas of necrosis and hemorrhage. Sections from the grossly positive node is given to both clinical and research tissue bank.

SECTION CODE: A1, mirror image normal skin; A2, mirror image grossly positive large lymph node; A3-A7, representative sections of the largest grossly positive lymph node; A8, A9, one lymph node, serially sectioned; A10-A12, one lymph node, serially sectioned; A13-A16, one lymph node, serially sectioned; A17, one lymph node, bisected; A18, one lymph node, bisected.

(B) COMMON ILIAC LYMPH NODES – A single fragment of fibroconnective tissue containing lymph nodes (11.0 x 1.3 cm x 0.5 cm).

Dissection reveals the presence of multiple lymph nodes ranging in size from 0.4 to 2.3 cm.

SECTION CODE: B1, one lymph node, serially sectioned, entirely submitted; B2, one lymph node, serially sectioned, entirely submitted; B3, one lymph node, bisected; B4, one lymph node, bisected; B5, three possible lymph nodes; B6, four possible lymph nodes.

(C) OBTURATOR NODE, LEFT – A single fragment of lobulated fibroconnective tissue (7.7 x 2.5 x 0.9 cm). Dissection reveals the presence of multiple lymph nodes ranging from 1.5 to 3.3 cm (largest lymph node 3.3 x 2.2 x 0.9 cm). The largest lymph node appears grossly to be a fatty lymph node.

SECTION CODE: C1-C3, one lymph node, serially sectioned, entirely submitted; C4, C5, one lymph node, serially sectioned, entirely submitted; C6, one lymph node, bisected, entirely submitted; C7, one lymph node, serially sectioned, entirely submitted; C8, one lymph node, bisected; C9, one lymph node, serially sectioned and entirely submitted; C10, three possible lymph nodes.

(D) LEFT STERNAL ILIAC NODES – Two fragments of fibroconnective tissue (10.0 x 3.4 x 1.5 cm) containing lymph nodes.

Dissection of the specimen reveals multiple lymph nodes ranging from 0.5 to 2.1 cm.

SECTION CODE: D1, one lymph node, serially sectioned, entirely submitted; D2, one lymph node, serially sectioned, entirely submitted; D3, one lymph node, bisected; D4, one lymph node, serially sectioned, entirely submitted; D5, D6, one lymph node, serially sectioned, entirely submitted; D7, one lymph node, bisected; D8, one possible lymph node, bisected; D9, one lymph

[page 2 of 2]
node, serially sectioned, entirely submitted; D10, one lymph node, bisected; D11, three possible lymph nodes; D12, four possible lymph nodes; D13, one possible lymph node, bisected.

CLINICAL HISTORY
Melanoma.

SNOMED CODES

T-02487 T-02487 T-02487 T-02487
M-87206 M-00110 M-87206 M-00110

Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration "

Entire report and diagnosis completed by:

These tests have not been

-----END OF REPORT-----

Source: NCI Genomic Data Commons file b37e5197-48c7-4872-9ecf-6f96f0bb071d (TCGA-D3-A5GR.2055FAF3-FB7C-4E13-8A17-FF4B9964F49F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).